Somatic mutation profile of tumor specimen TCGA-KC-A7FD-01A (aliquot TCGA-KC-A7FD-01A-11D-A33T-08) from TCGA case TCGA-KC-A7FD, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.3 years (22,745 days).
Specimen TCGA-KC-A7FD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b62dc507-943a-4f50-94d9-91584b501f02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KC-A7FD-10A (Blood Derived Normal), aliquot TCGA-KC-A7FD-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1691450c-f511-4375-b29b-800a03f50d96

The open-access MAF lists 39 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Nonsense Mutation 3, Frame Shift Del 3, In Frame Del 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL7B | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.104); catalogued as rs761937962, COSV65927502; called by muse, mutect2, varscan2
- ADGRV1 | c.13254C>G p.I4418M | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV101315442; called by muse, mutect2, varscan2
- ARHGEF2 | c.1410G>C p.R470S (on ENST00000361247 / NM_001162383.2; = p.R442S on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100559984; called by muse, mutect2, varscan2
- ATF7 | c.632C>G p.A211G (on ENST00000548446 / NM_001366555.2; = p.A200G on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1274279486, COSV100129125; called by muse, mutect2, varscan2
- COL10A1 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99684045; called by muse, mutect2, varscan2
- COL7A1 | c.3646G>A p.V1216M | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs150513888; called by muse, mutect2, varscan2
- KLHL18 | c.261-2A>G p.X87_splice | Splice Site (SNP) | VAF 23/49 reads (47%) | catalogued as COSV99230478; called by muse, mutect2, varscan2
- KMT2C | c.3016G>C p.E1006Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100066249, COSV100068517; called by muse, mutect2, varscan2
- MTG1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.309); catalogued as COSV100448671, COSV100448952; called by muse, mutect2, varscan2
- NFX1 | c.1449G>T p.R483S | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100581759; called by muse, mutect2, varscan2
- NFX1 | c.1450C>T p.H484Y | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV100581760; called by muse, mutect2, varscan2
- OR10K2 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100149377, COSV59221829; called by muse, mutect2, varscan2
- OR2T10 | c.820T>C p.S274P | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV57896369; called by muse, mutect2, varscan2
- PCDH17 | c.3091G>A p.E1031K | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.094); catalogued as COSV100931410; called by muse, mutect2
- PLCL2 | c.429G>C p.M143I (on ENST00000615277 / NM_001144382.2; = p.M17I on NM_015184.5) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101196551, COSV101196887; called by muse, mutect2, varscan2
- PTPRU | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1464102140, COSV100111476; called by muse, mutect2, varscan2
- SLC17A6 | c.463T>A p.F155I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99580664; called by muse, mutect2, varscan2
- SPTA1 | c.1803G>C p.K601N | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100934184, COSV63754771; called by muse, mutect2, varscan2
- TTN | c.84307G>A p.A28103T (on ENST00000591111; = p.A20679T on NM_003319.4) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | PolyPhen benign (0); catalogued as rs201592005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TYR | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs36006590, CM090092; called by muse, mutect2, varscan2
- UBXN7 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 55/144 reads (38%) | catalogued as COSV99580745; called by muse, mutect2, varscan2
- VCP | c.794T>C p.F265S | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100734087; called by muse, mutect2, varscan2
- VCP | c.793T>G p.F265V | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100734089; called by muse, mutect2, varscan2
- WDR17 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99706697; called by muse, mutect2, varscan2
- ZFHX3 | c.3802C>T p.Q1268* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as COSV99195147; called by muse, mutect2, varscan2
- ZNF208 | c.1345G>T p.G449* | Nonsense Mutation (SNP) | VAF 7/84 reads (8%) | catalogued as COSV101236773; called by muse, mutect2
- ZNF317 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs769905916, COSV56108972; called by muse, mutect2, varscan2
- BAZ2B | c.2487_2489del p.K830del | In Frame Del (DEL) | VAF 19/47 reads (40%) | called by mutect2, pindel*, varscan2*
- BTG1 | c.488del p.N163Tfs*4 | Frame Shift Del (DEL) | VAF 34/106 reads (32%) | called by mutect2, pindel, varscan2
- CBWD6 | c.613del p.T205Qfs*9 | Frame Shift Del (DEL) | VAF 67/215 reads (31%) | called by mutect2, pindel, varscan2
- UNC79 | c.5666del p.P1889Lfs*3 (on ENST00000393151 / NM_001346218.2; = p.P1712Lfs*3 on NM_020818.5) | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
- GEMIN4 | c.1461C>T p.Y487= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs758441347, COSV100021186; called by muse, mutect2, varscan2
- ITPR1 | c.5334A>G p.G1778= (on ENST00000354582; = p.G1723= on NM_002222.7) | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100229426; called by muse, mutect2
- KAZN | c.978C>T p.A326= | Silent (SNP) | VAF 9/125 reads (7%) | catalogued as rs765040060, COSV100747645; called by muse, mutect2
- NWD1 | c.774C>T p.H258= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs770995497, COSV60342333; called by muse, mutect2, varscan2
- PIK3R4 | c.1200A>G p.E400= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as rs1346457437, COSV100768197; called by muse, mutect2
- PRAMEF20 | c.840C>T p.L280= | Silent (SNP) | VAF 19/383 reads (5%) | called by muse, mutect2
- RBMXL2 | c.906C>T p.Y302= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs774916563, COSV100182057; called by muse, mutect2
- IKZF3 | c.-1C>A | 5'UTR (SNP) | VAF 37/100 reads (37%) | catalogued as COSV53105474; called by muse, mutect2, varscan2
